Somatic mutation profile of tumor specimen BA2481D (aliquot aq-BA2481D) from BEATAML1.0 case 2159, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Refractory anemia with excess blasts; Tissue or organ of origin: Bone marrow.
Specimen BA2481D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 521883a7-c0c1-4f9c-9aab-48f614c99606.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2247D (Solid Tissue Normal), aliquot aq-BA2247D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b100f464-0cbd-4f82-a81b-73b3495d2de1

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1, Splice Region 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC63 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as rs771937207, COSV57528506, COSV57531266; called by muse, mutect2, varscan2
- EZH2 | c.1942C>T p.Q648* (on ENST00000460911 / NM_001203247.2; = p.Q653* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 47/113 reads (42%) | catalogued as COSV57450023, COSV57459965; called by muse, mutect2, varscan2
- POLQ | c.7312G>A p.G2438R | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140405584; called by mutect2, varscan2
- RYR3 | c.7849G>A p.V2617I (on ENST00000389232; = p.V2618I on NM_001036.6) | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs369629619; ClinVar: likely benign; called by muse, mutect2, varscan2
- APLP1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL9 | c.5025G>A p.E1675= | Splice Region (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- GAR1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1A | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TDRD12 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP2A1 | c.2250C>T p.G750= | Silent (SNP) | VAF 76/200 reads (38%) | called by muse, mutect2, varscan2
- GPR108 | c.957C>T p.S319= (on ENST00000264080 / NM_001080452.1; = p.S77= on NM_020171.2) | Silent (SNP) | VAF 57/135 reads (42%) | called by muse, mutect2, varscan2
- PLCB2 | c.2577G>A p.L859= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as rs1341011224; called by muse, mutect2, varscan2
- TNN | c.3876G>T p.L1292= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- NBPF9 | c.2476+1592G>A | Intron (SNP) | VAF 6/157 reads (4%) | catalogued as rs678781; called by muse, mutect2
- SHH | c.*2255G>A | 3'UTR (SNP) | VAF 56/116 reads (48%) | catalogued as rs1307799601; called by muse, varscan2
